Gene-level copy-number profile of tumor specimen MP2PRT-PARCYM-TMP1-A from MP2PRT case MP2PRT-PARCYM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (888 days).
Specimen MP2PRT-PARCYM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 43f7f816-f93e-42ed-b6dc-b4772d2e90de.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARCYM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/189d37c3-fe10-4c5f-8dbe-9b88f5348327

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3; copy number 2: 512; copy number 3: 113; copy number 4: 42,101; copy number 5: 244; copy number 6: 15,162; copy number 7: 60; copy number 8: 694; copy number 9: 18; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,691,760–248,716,755, 1 gene (within-gene range 0–5): LYPD9P.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,936,581–248,937,043, 1 gene, copy number 10: RPL23AP25.
- chr21:46,188,141–46,691,226, 18 genes, copy number 9 (within-gene range 8–9): LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
